Surgical pathology report (de-identified scan), TCGA case TCGA-P5-A5EU, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Cureline, specimen TCGA-P5-A5EU-01A (Primary Tumor).

Index					Sex	Ethnicity (Race)	Clinical Diagnosis	Date of procurement	Anatomical Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format	Container	Number of containers	Amount per container	Unit	Type of Procurement	Histological description (Source)	Grade (source)	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Treatment type	Component of treatment (Chemo / Horm Th Details)	Tumor cell %
					male	Caucasian (White)	Glioma		Brain, both frontal lobes and corpus callosum	Primary	Tumor	Tissue	OCT	block	1	200	mg	surgery	Anaplastic astrocytoma	3	n/a	n/a	n/a	none	n/a	80
					male	Caucasian (White)	Glioma		Blood	n/a	Normal	Blood	frozen	tube	1	4	ml	blood draw	n/a	n/a	n/a	n/a	n/a	none	n/a	n/a

ICD-3
Astrocytoma, anaplastic 9401/3
Site (R+L) Brain, supratentorial
C71.0
JW 4/2/13

Source: NCI Genomic Data Commons file e85921d5-0b13-475e-8e2f-b95a09091267 (TCGA-P5-A5EU.47CE1D35-2BA2-472B-AF22-42EBEAF45C19.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).